Somatic mutation profile of tumor specimen ALCH-AFF7-TTP1-A (aliquot ALCH-AFF7-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AFF7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.1 years (22,314 days).
Specimen ALCH-AFF7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3714252f-0f52-45f7-b696-f22cea16e519.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFF7-NB1-A (Blood Derived Normal), aliquot ALCH-AFF7-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24266d6d-2bf1-4831-97d8-3179895eade4

The open-access MAF lists 264 somatic variants for this specimen: 184 protein-altering or splice-affecting, 50 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 159, Silent 50, Intron 13, Nonsense Mutation 12, Splice Site 8, 3'UTR 7, 5'UTR 4, Frame Shift Del 3, RNA 3, 5'Flank 2, Splice Region 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 100/646 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121908469, CM012887, COSV63020562; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 57/610 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCA1 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 42/702 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.489); catalogued as rs766885355; called by muse, mutect2
- ABCA8 | c.1351G>A p.V451M | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs746721593, COSV99285738; called by muse, mutect2
- ABCB1 | c.3673C>A p.R1225S | Missense Mutation (SNP) | VAF 181/1057 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55954222; called by muse, mutect2, varscan2
- ACER1 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs200048395; called by muse, mutect2
- ADGB | c.2161T>C p.S721P | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1193307054; called by muse, mutect2, varscan2
- AFF2 | c.2885G>T p.C962F | Missense Mutation (SNP) | VAF 59/362 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.796); catalogued as rs1212059076; called by muse, mutect2, varscan2
- ARPP21 | c.2110G>A p.V704M | Missense Mutation (SNP) | VAF 43/465 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as rs894763514, COSV51802791; called by muse, mutect2
- BCHE | c.839G>T p.C280F | Missense Mutation (SNP) | VAF 40/529 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52261817; called by muse, mutect2
- BTNL9 | c.553C>A p.Q185K | Missense Mutation (SNP) | VAF 39/572 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.54); catalogued as COSV100576071; called by muse, mutect2
- CASP8AP2 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1240367867; called by muse, mutect2, varscan2
- CNKSR1 | c.1063G>T p.E355* (on ENST00000374253 / NM_001297647.2; = p.E348* on NM_006314.3) | Nonsense Mutation (SNP) | VAF 24/280 reads (9%) | catalogued as COSV64162925; called by muse, mutect2
- CNTN1 | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 65/644 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780982356; called by muse, mutect2, varscan2
- CNTN5 | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs773455557; called by muse, mutect2, varscan2
- CYFIP2 | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 34/386 reads (9%) | catalogued as COSV59041105; called by muse, mutect2
- CYSLTR2 | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as rs759049153, COSV56165521, COSV56165738; called by muse, mutect2
- DGKA | c.1402G>T p.A468S | Missense Mutation (SNP) | VAF 18/457 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as rs1219226711; called by muse, mutect2
- DIAPH3 | c.2431G>T p.E811* (on ENST00000400324 / NM_001042517.2; = p.E548* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 36/428 reads (8%) | catalogued as COSV57381773; called by muse, mutect2
- EPHB3 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57808198; called by muse, mutect2
- F5 | c.3632C>A p.T1211K | Missense Mutation (SNP) | VAF 41/476 reads (9%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.247); catalogued as COSV63122961; called by muse, mutect2
- FASTKD5 | c.1552G>T p.D518Y | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53906170; called by muse, mutect2, varscan2
- IGHV1-2 | c.146C>A p.T49N | Missense Mutation (SNP) | VAF 49/621 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs11553011; called by muse, mutect2
- IGSF10 | c.6433C>G p.Q2145E | Missense Mutation (SNP) | VAF 18/633 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.257); catalogued as COSV56372393; called by muse, mutect2
- INSYN2B | c.1571C>A p.T524N | Missense Mutation (SNP) | VAF 53/523 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as rs1561774897; called by muse, mutect2, varscan2
- KCNB2 | c.2644G>A p.G882R | Missense Mutation (SNP) | VAF 16/599 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.423); catalogued as rs1332096458; called by muse, mutect2
- KDM3A | c.3017T>A p.L1006Q | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57225469; called by muse, mutect2
- KRTAP19-7 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 69/398 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.207); catalogued as COSV100603218; called by muse, mutect2, varscan2
- LRRTM4 | c.406C>A p.R136S | Missense Mutation (SNP) | VAF 40/503 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69142013; called by muse, mutect2
- MARCHF11 | c.1055G>T p.R352L | Missense Mutation (SNP) | VAF 93/824 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV60126833; called by muse, mutect2, varscan2
- MTUS2 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.116); catalogued as COSV70914600; called by muse, mutect2
- MUC16 | c.28966G>T p.E9656* | Nonsense Mutation (SNP) | VAF 18/364 reads (5%) | catalogued as COSV101197444; called by muse, mutect2
- MUC16 | c.24242C>G p.S8081C | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.437); catalogued as COSV101198298; called by muse, mutect2
- MUC16 | c.13061C>G p.S4354* | Nonsense Mutation (SNP) | VAF 14/254 reads (6%) | catalogued as COSV67478836; called by muse, mutect2
- MXRA5 | c.5875G>T p.D1959Y | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54227320; called by muse, mutect2
- MYO1A | c.430+1G>A p.X144_splice | Splice Site (SNP) | VAF 24/272 reads (9%) | catalogued as rs1316994560; called by muse, mutect2
- NBAS | c.3963G>C p.Q1321H | Missense Mutation (SNP) | VAF 59/644 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV55719610; called by muse, mutect2
- NLRP14 | c.2405G>T p.G802V | Missense Mutation (SNP) | VAF 64/732 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167290724; called by muse, mutect2
- NPY5R | c.746T>A p.L249H | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as COSV100642979; called by muse, mutect2, varscan2
- OR1N1 | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100509697; called by muse, mutect2, varscan2
- PCDH8 | c.419T>A p.I140N | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.762); catalogued as rs1311744473; called by muse, mutect2
- PCDHA2 | c.2048G>C p.W683S | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs781870691; called by muse, mutect2
- PDE1C | c.2071G>T p.D691Y | Missense Mutation (SNP) | VAF 52/311 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs778260273; called by muse, mutect2, varscan2
- PEG3 | c.934G>C p.G312R | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55642239; called by muse, varscan2
- PIK3R5 | c.2533G>A p.D845N | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs373411680; called by muse, mutect2, varscan2
- RUNDC3B | c.261G>T p.W87C | Missense Mutation (SNP) | VAF 20/488 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.703); catalogued as COSV55951177; called by muse, mutect2
- RYR2 | c.11881G>T p.D3961Y | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63668496; called by muse, mutect2, varscan2
- SNTB1 | c.749A>G p.Y250C | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs1437543800; called by muse, mutect2
- SPATA31A1 | c.2903C>A p.A968E | Missense Mutation (SNP) | VAF 98/1222 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV66533822; called by muse, mutect2
- SPATA31A6 | c.3266G>T p.C1089F | Missense Mutation (SNP) | VAF 79/955 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as COSV60534723; called by muse, mutect2
- STAT5B | c.2110A>T p.I704F | Missense Mutation (SNP) | VAF 86/828 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV53183709; called by muse, mutect2, varscan2
- TAF1L | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 70/768 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.558); catalogued as rs770181009; called by muse, mutect2
- TENT5D | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100382782; called by muse, mutect2, varscan2
- TPO | c.2028C>A p.H676Q | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as rs747296289, COSV61095451; called by muse, mutect2
- TRPA1 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 63/791 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51559150; called by muse, mutect2
- ZNF497 | c.1313G>C p.G438A | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs569431577; called by muse, mutect2, varscan2
- AADACL4 | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 39/659 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- AC004593.2 | c.1436G>T p.R479L | Missense Mutation (SNP) | VAF 30/427 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2
- ACACA | c.7070T>G p.I2357S | Missense Mutation (SNP) | VAF 28/624 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.054); called by muse, mutect2
- ACAN | c.2423C>T p.S808L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, varscan2
- AL445989.1 | c.132T>A p.Y44* | Nonsense Mutation (SNP) | VAF 32/582 reads (5%) | called by muse, mutect2
- ALMS1 | c.2836G>T p.G946W | Missense Mutation (SNP) | VAF 46/410 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ANK1 | c.668A>T p.Q223L | Missense Mutation (SNP) | VAF 44/802 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); called by muse, mutect2
- ANXA3 | c.828G>T p.M276I | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ARHGEF3 | c.1042-1G>T p.X348_splice | Splice Site (SNP) | VAF 30/232 reads (13%) | called by muse, mutect2
- ARMCX2 | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP12A | c.976G>A p.V326M | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.153); called by muse, mutect2
- C16orf96 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 49/518 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.444); called by muse, varscan2
- CA10 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.014); called by muse, mutect2
- CAPN13 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- CCDC88B | c.2455G>T p.A819S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- CDH4 | c.2429C>A p.P810Q | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CFAP61 | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 26/324 reads (8%) | called by muse, mutect2
- CHST3 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 39/373 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CMTR2 | c.600G>A p.W200* | Nonsense Mutation (SNP) | VAF 18/176 reads (10%) | called by muse, mutect2
- CNTNAP3 | c.3632C>A p.S1211Y | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2
- COL20A1 | c.3613+7C>T | Splice Region (SNP) | VAF 32/277 reads (12%) | called by muse, mutect2, varscan2
- CSMD3 | c.7136C>A p.T2379K (on ENST00000297405 / NM_001363185.1; = p.T2275K on NM_052900.3) | Missense Mutation (SNP) | VAF 124/872 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CTTNBP2 | c.1901C>A p.S634Y | Missense Mutation (SNP) | VAF 45/415 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP2A6 | c.220G>C p.G74R | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DBF4 | c.2018G>T p.G673V | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, varscan2
- DCHS1 | c.9488G>T p.W3163L | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); called by muse, mutect2
- DCTN4 | c.413A>T p.N138I | Missense Mutation (SNP) | VAF 41/528 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- DDX25 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 48/344 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND4C | c.4779A>G p.A1593= (on ENST00000434457 / NM_001330640.2; = p.A1544= on NM_017925.7) | Splice Region (SNP) | VAF 8/78 reads (10%) | called by muse, varscan2
- DNAH9 | c.11529G>C p.K3843N | Missense Mutation (SNP) | VAF 34/383 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DSG4 | c.1802C>A p.A601E | Missense Mutation (SNP) | VAF 52/488 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EPHA8 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2
- EPHB6 | c.312C>A p.H104Q | Missense Mutation (SNP) | VAF 64/626 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPRS1 | c.3586G>T p.V1196L | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- EPS8L3 | c.178del p.Q60Rfs*9 | Frame Shift Del (DEL) | VAF 49/458 reads (11%) | called by mutect2, pindel, varscan2
- ERICH3 | c.3004G>T p.E1002* | Nonsense Mutation (SNP) | VAF 20/297 reads (7%) | called by muse, mutect2
- EYS | c.3114C>A p.H1038Q | Missense Mutation (SNP) | VAF 56/440 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- FBXL7 | c.989G>C p.S330T | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FBXO21 | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 19/247 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2
- FER1L6 | c.448-1G>C p.X150_splice | Splice Site (SNP) | VAF 38/422 reads (9%) | called by muse, mutect2
- FMO4 | c.331_332del p.C111Qfs*26 | Frame Shift Del (DEL) | VAF 14/148 reads (9%) | called by pindel, varscan2
- FOXP1 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- FRMD4B | c.2185G>T p.G729W | Missense Mutation (SNP) | VAF 53/436 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FSIP1 | c.154G>C p.G52R | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2
- GLYATL3 | c.580C>G p.R194G | Missense Mutation (SNP) | VAF 78/632 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GPBAR1 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 27/370 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.09); called by muse, mutect2
- H3-5 | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 46/586 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HHLA1 | c.1513T>A p.Y505N | Missense Mutation (SNP) | VAF 63/541 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- HNRNPH3 | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, mutect2
- IQSEC2 | c.2254G>T p.V752F (on ENST00000642864 / NM_001111125.3; = p.V547F on NM_015075.2) | Missense Mutation (SNP) | VAF 64/436 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIF20B | c.4069A>G p.I1357V (on ENST00000371728 / NM_001284259.2; = p.I1317V on NM_016195.4) | Missense Mutation (SNP) | VAF 21/455 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- KIF9 | c.11G>T p.R4M | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2
- KRT2 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 33/668 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA1 | c.7562G>T p.G2521V | Missense Mutation (SNP) | VAF 40/480 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA5 | c.7300A>T p.R2434W | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2
- LAMB3 | c.3034C>A p.Q1012K | Missense Mutation (SNP) | VAF 114/790 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- LRP10 | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- LRRC8D | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 57/458 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- LTBP4 | c.2833A>T p.I945F (on ENST00000308370 / NM_001042544.1; = p.I908F on NM_003573.2) | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.175); called by muse, mutect2
- LUC7L2 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 29/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LYST | c.6200G>T p.S2067I | Missense Mutation (SNP) | VAF 68/887 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); called by muse, mutect2
- MAP2 | c.4487C>T p.P1496L | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MPPED2 | c.57C>A p.S19R | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC16 | c.21005C>A p.S7002Y | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2
- MUC19 | c.909+1G>A p.X303_splice | Splice Site (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- MYCBP2 | c.8531G>T p.R2844L (on ENST00000357337; = p.R2882L on NM_015057.5) | Missense Mutation (SNP) | VAF 23/389 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- MYO18B | c.6115G>T p.V2039L | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2
- NIN | c.5288C>T p.A1763V (on ENST00000382041 / NM_182946.1; = p.A1050V on NM_016350.4) | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NISCH | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 39/406 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- NOVA2 | c.1276G>T p.G426C | Missense Mutation (SNP) | VAF 81/696 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOXO1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPHP3 | c.1771G>T p.A591S | Missense Mutation (SNP) | VAF 68/634 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRCAM | c.3104G>C p.G1035A (on ENST00000379028 / NM_001371124.1; = p.G1019A on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/493 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSD3 | c.3434C>G p.P1145R | Missense Mutation (SNP) | VAF 23/357 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- NT5C1A | c.321C>A p.N107K | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2
- OR51B6 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by muse, mutect2
- OR8A1 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OTOA | c.399+1G>T p.X133_splice | Splice Site (SNP) | VAF 44/618 reads (7%) | called by muse, mutect2
- PAM | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 53/446 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PCDHAC2 | c.639G>C p.K213N | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PCDHB2 | c.2077G>T p.V693L | Missense Mutation (SNP) | VAF 57/714 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); called by muse, mutect2
- PCDHB4 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PDLIM7 | c.1228G>C p.G410R | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PEG3 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PGA5 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 60/450 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIEZO2 | c.2519C>A p.P840Q | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.338); called by muse, mutect2
- PIF1 | c.1526G>A p.R509K | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLA2G4C | c.763+1G>A p.X255_splice | Splice Site (SNP) | VAF 22/354 reads (6%) | called by muse, mutect2
- PPFIA2 | c.2831G>C p.G944A | Missense Mutation (SNP) | VAF 72/728 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- PPP1R2B | c.184G>T p.G62C | Missense Mutation (SNP) | VAF 98/968 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RAG1 | c.977G>T p.S326I | Missense Mutation (SNP) | VAF 88/828 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RBM26 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- RNF214 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ROBO2 | c.2501-2A>G p.X834_splice | Splice Site (SNP) | VAF 30/278 reads (11%) | called by muse, mutect2, varscan2
- SAMD9L | c.4549G>T p.E1517* | Nonsense Mutation (SNP) | VAF 13/237 reads (5%) | called by muse, mutect2
- SGIP1 | c.1016C>A p.T339K | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SH2D4B | c.859A>T p.S287C (on ENST00000646907; = p.R287W on NM_207372.2) | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2
- SLC27A4 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.41); called by muse, mutect2
- SLITRK3 | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 23/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLK | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 34/511 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMC1A | c.2880G>T p.E960D | Missense Mutation (SNP) | VAF 29/595 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- SMC2 | c.2990G>T p.R997L | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- SP8 | c.359C>T p.P120L (on ENST00000361443 / NM_198956.4; = p.P138L on NM_182700.6) | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- SP8 | c.148A>T p.S50C (on ENST00000361443 / NM_198956.4; = p.S68C on NM_182700.6) | Missense Mutation (SNP) | VAF 80/790 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPAG1 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPAG17 | c.2352T>A p.F784L | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.182); called by muse, mutect2
- SRGAP1 | c.1985C>T p.T662I | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SRGAP3 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 26/684 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2
- TAF4B | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, varscan2
- TAF5L | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 29/309 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- THSD7B | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 47/442 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TLL2 | c.1153C>A p.P385T | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- TMC1 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 47/380 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); called by mutect2, varscan2
- TRBV3-1 | c.306del p.G103Vfs*? | Frame Shift Del (DEL) | VAF 22/209 reads (11%) | called by mutect2, pindel
- TUBA3E | c.117T>A p.D39E | Missense Mutation (SNP) | VAF 12/406 reads (3%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2
- UBE2U | c.250C>A p.H84N | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UHRF1BP1 | c.208-1G>T p.X70_splice | Splice Site (SNP) | VAF 30/356 reads (8%) | called by muse, mutect2
- UNC13A | c.2914C>A p.L972I | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.349); called by muse, mutect2
- USH2A | c.7850T>C p.V2617A | Missense Mutation (SNP) | VAF 68/679 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- VCAN | c.2590C>A p.Q864K | Missense Mutation (SNP) | VAF 33/471 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2
- WFS1 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 60/559 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ZNF217 | c.584G>T p.S195I | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.091); called by muse, mutect2
- ZNF304 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ZNF365 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 33/523 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); called by muse, mutect2
- ZNF462 | c.6885G>T p.L2295F | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF485 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 21/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF629 | c.955C>A p.R319S | Missense Mutation (SNP) | VAF 25/334 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZXDB | c.1129G>T p.A377S | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2
- ABCA12 | c.6867T>C p.L2289= (on ENST00000272895 / NM_173076.3; = p.L1971= on NM_015657.3) | Silent (SNP) | VAF 70/704 reads (10%) | called by muse, mutect2
- ADGRL3 | c.432C>T p.I144= (on ENST00000506720 / NM_001322402.2; = p.I76= on NM_015236.6) | Silent (SNP) | VAF 31/277 reads (11%) | catalogued as COSV72266102, COSV72273789; called by muse, mutect2, varscan2
- AK5 | c.195G>A p.K65= (on ENST00000354567 / NM_174858.3; = p.K39= on NM_012093.4) | Silent (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- APOB | c.1128C>A p.P376= | Silent (SNP) | VAF 56/968 reads (6%) | called by muse, mutect2
- BCHE | c.840C>T p.C280= | Silent (SNP) | VAF 40/518 reads (8%) | called by muse, mutect2
- CCDC88B | c.2454G>T p.L818= | Silent (SNP) | VAF 12/112 reads (11%) | called by muse, varscan2
- CCM2 | c.123T>A p.P41= | Silent (SNP) | VAF 69/599 reads (12%) | called by muse, mutect2, varscan2
- CFAP46 | c.7890C>A p.S2630= | Silent (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- COL11A2 | c.1983G>A p.G661= (on ENST00000341947 / NM_080680.3; = p.G554= on NM_080679.2) | Silent (SNP) | VAF 37/317 reads (12%) | catalogued as COSV59496682; called by muse, mutect2, varscan2
- COL16A1 | c.3762A>G p.P1254= | Silent (SNP) | VAF 21/498 reads (4%) | called by muse, mutect2
- COL1A2 | c.2346C>T p.P782= | Silent (SNP) | VAF 73/756 reads (10%) | called by muse, mutect2
- CYP26A1 | c.603G>T p.A201= | Silent (SNP) | VAF 22/378 reads (6%) | catalogued as rs910741564, COSV56417512; called by muse, mutect2
- DDC | c.297C>T p.G99= | Silent (SNP) | VAF 33/841 reads (4%) | called by muse, mutect2
- DKKL1 | c.48C>T p.V16= | Silent (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- EIF3K | c.462C>T p.D154= | Silent (SNP) | VAF 11/129 reads (9%) | called by muse, mutect2
- FLG | c.10014T>C p.S3338= | Silent (SNP) | VAF 72/566 reads (13%) | catalogued as COSV104425351; called by muse, mutect2
- FNDC7 | c.1524C>T p.T508= | Silent (SNP) | VAF 80/543 reads (15%) | called by muse, mutect2, varscan2
- FOXB2 | c.42G>T p.P14= | Silent (SNP) | VAF 32/477 reads (7%) | catalogued as COSV100942409, COSV65023597; called by muse, mutect2
- GRIN3A | c.69G>T p.L23= | Silent (SNP) | VAF 24/189 reads (13%) | called by muse, mutect2, varscan2
- GSG1L2 | c.663G>T p.S221= | Silent (SNP) | VAF 40/296 reads (14%) | called by muse, mutect2, varscan2
- LRRTM4 | c.405C>A p.L135= | Silent (SNP) | VAF 40/502 reads (8%) | catalogued as COSV69140436; called by muse, mutect2
- MAGEB3 | c.450T>A p.P150= | Silent (SNP) | VAF 45/323 reads (14%) | called by muse, mutect2, varscan2
- MUC16 | c.15363A>C p.I5121= | Silent (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- MYCBP2 | c.7533G>T p.L2511= (on ENST00000357337; = p.L2549= on NM_015057.5) | Silent (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- NCOR2 | c.4542C>T p.T1514= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs929491817, COSV62299395; called by muse, mutect2, varscan2
- NLRP3 | c.2256G>T p.G752= | Silent (SNP) | VAF 96/759 reads (13%) | catalogued as COSV60221127; called by muse, varscan2
- NUTM2G | c.1107C>T p.T369= | Silent (SNP) | VAF 68/576 reads (12%) | called by muse, mutect2, varscan2
- OR2A14 | c.117G>T p.L39= | Silent (SNP) | VAF 36/456 reads (8%) | catalogued as rs1563053838; called by muse, mutect2
- PEG3 | c.1275C>A p.A425= | Silent (SNP) | VAF 24/236 reads (10%) | called by muse, mutect2
- PPFIBP1 | c.2094A>T p.R698= (on ENST00000318304 / NM_177444.3; = p.R692= on NM_003622.4) | Silent (SNP) | VAF 32/373 reads (9%) | called by muse, mutect2
- RASAL2 | c.1818T>C p.P606= | Silent (SNP) | VAF 70/635 reads (11%) | called by muse, mutect2, varscan2
- RBBP9 | c.24G>A p.V8= | Silent (SNP) | VAF 16/458 reads (3%) | called by muse, mutect2
- SBF2 | c.2058C>T p.L686= | Silent (SNP) | VAF 56/475 reads (12%) | called by muse, mutect2, varscan2
- SERPINA5 | c.72C>A p.P24= | Silent (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- SHROOM3 | c.3330G>C p.G1110= | Silent (SNP) | VAF 28/188 reads (15%) | called by muse, mutect2, varscan2
- SLC13A4 | c.498C>A p.L166= | Silent (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- SLC5A5 | c.648C>A p.P216= | Silent (SNP) | VAF 44/578 reads (8%) | called by muse, mutect2
- SLC8A3 | c.2487C>A p.A829= (on ENST00000381269 / NM_183002.3; = p.A827= on NM_033262.4) | Silent (SNP) | VAF 27/212 reads (13%) | catalogued as rs112896508; called by muse, mutect2, varscan2
- SLFN12L | c.354G>A p.Q118= (on ENST00000260908 / NM_001363830.1; = p.Q136= on NM_001195790.1) | Silent (SNP) | VAF 13/258 reads (5%) | catalogued as COSV99609919; called by muse, mutect2
- SMAD2 | c.891C>T p.L297= | Silent (SNP) | VAF 75/932 reads (8%) | called by muse, mutect2
- SPNS2 | c.1515C>T p.L505= | Silent (SNP) | VAF 16/341 reads (5%) | catalogued as rs1347883016, COSV99626960; called by muse, mutect2
- SSC5D | c.4074C>A p.V1358= | Silent (SNP) | VAF 43/337 reads (13%) | called by muse, mutect2, varscan2
- SYNPO2 | c.1638G>T p.T546= | Silent (SNP) | VAF 14/230 reads (6%) | catalogued as COSV61109649; called by muse, mutect2
- THBS2 | c.2490T>A p.G830= | Silent (SNP) | VAF 31/326 reads (10%) | called by muse, mutect2
- VWA5B1 | c.324C>A p.A108= | Silent (SNP) | VAF 22/262 reads (8%) | called by muse, mutect2
- VWC2 | c.720C>T p.R240= | Silent (SNP) | VAF 87/358 reads (24%) | called by muse, mutect2, varscan2
- WDR87 | c.1269G>T p.L423= | Silent (SNP) | VAF 52/402 reads (13%) | called by muse, mutect2, varscan2
- WIZ | c.5355A>T p.A1785= (on ENST00000673675 / NM_001371589.1; = p.A690= on NM_021241.3) | Silent (SNP) | VAF 15/198 reads (8%) | called by muse, mutect2
- ZNF669 | c.1077G>A p.E359= | Silent (SNP) | VAF 63/475 reads (13%) | called by muse, mutect2, varscan2
- ZPBP | c.798A>T p.I266= | Silent (SNP) | VAF 39/358 reads (11%) | called by muse, mutect2, varscan2
- AC008592.1 | chr5:95858940 C>T | 5'Flank (SNP) | VAF 18/172 reads (10%) | called by muse, varscan2
- C9orf129 | n.628G>A | RNA (SNP) | VAF 56/624 reads (9%) | catalogued as rs1301739376; called by muse, mutect2
- C9orf24 | c.*12G>C | 3'UTR (SNP) | VAF 31/317 reads (10%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811799 C>A | 3'Flank (SNP) | VAF 12/95 reads (13%) | catalogued as rs1314629451; called by muse, mutect2
- COL25A1 | c.1656+3572G>T | Intron (SNP) | VAF 73/721 reads (10%) | called by muse, mutect2, varscan2
- COLEC11 | c.-1G>A | 5'UTR (SNP) | VAF 22/294 reads (7%) | catalogued as rs1339384030, COSV52592931; called by muse, mutect2
- CYYR1 | c.-303C>A | 5'UTR (SNP) | VAF 22/232 reads (9%) | called by muse, mutect2, varscan2
- DUOX2 | c.1399-40G>T | Intron (SNP) | VAF 16/119 reads (13%) | called by muse, mutect2, varscan2
- KLF6 | c.*1947C>A | 3'UTR (SNP) | VAF 77/642 reads (12%) | called by muse, varscan2
- LCN1 | c.*125C>A | 3'UTR (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- LINC02817 | n.372C>T | RNA (SNP) | VAF 50/532 reads (9%) | called by muse, mutect2
- MAP4K1 | c.*66C>A | 3'UTR (SNP) | VAF 54/367 reads (15%) | called by muse, mutect2, varscan2
- MINDY3 | c.-11G>T | 5'UTR (SNP) | VAF 95/524 reads (18%) | called by muse, mutect2, varscan2
- MIR496 | n.2C>T | RNA (SNP) | VAF 18/268 reads (7%) | catalogued as rs1459805503; called by muse, mutect2
- MSRB1 | c.204+29C>G | Intron (SNP) | VAF 24/296 reads (8%) | catalogued as rs376065678; called by muse, mutect2
- NDRG4 | c.22-84G>T | Intron (SNP) | VAF 25/367 reads (7%) | called by muse, mutect2
- OSBPL2 | chr20:62233232 C>T | 5'Flank (SNP) | VAF 20/145 reads (14%) | called by muse, mutect2, varscan2
- PCOLCE2 | c.449-214G>T | Intron (SNP) | VAF 27/450 reads (6%) | called by muse, mutect2
- PDE11A | c.2244+10T>A | Intron (SNP) | VAF 32/686 reads (5%) | called by muse, mutect2
- PDGFRA | c.2323+1102G>T | Intron (SNP) | VAF 29/267 reads (11%) | called by muse, mutect2, varscan2
- RIMS2 | c.699-4662A>G | Intron (SNP) | VAF 15/178 reads (8%) | catalogued as rs1310854333; called by muse, mutect2
- SYNE2 | c.18540+38C>G | Intron (SNP) | VAF 30/406 reads (7%) | called by muse, mutect2
- TBRG4 | c.-97G>T | 5'UTR (SNP) | VAF 55/237 reads (23%) | called by muse, mutect2, varscan2
- TLR4 | c.*35G>T | 3'UTR (SNP) | VAF 14/354 reads (4%) | called by muse, mutect2
- TROAP | c.2098+131C>A | Intron (SNP) | VAF 12/114 reads (11%) | catalogued as COSV57744245; called by muse, mutect2
- TROAP | c.2098+132C>A | Intron (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- UGT1A6 | c.862-23324G>A | Intron (SNP) | VAF 64/678 reads (9%) | catalogued as rs199592554, COSV59383041; called by muse, mutect2
- UQCRB | c.*1078A>G | 3'UTR (SNP) | VAF 42/504 reads (8%) | called by muse, mutect2
- UQCRB | c.*1077C>G | 3'UTR (SNP) | VAF 43/500 reads (9%) | called by muse, mutect2
- ZNF268 | c.457+1437G>T | Intron (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
